CCDI case PBCDYY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/1c937f5b-971b-4d6b-bf33-897d4d118e5d

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.2 years (444 days).

Biospecimens (3 samples)
- Sample 0DPJSF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPJSQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPJT9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
